Somatic mutation profile of tumor specimen TARGET-10-PAPFAT-09A (aliquot TARGET-10-PAPFAT-09A-01D) from TARGET case TARGET-10-PAPFAT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,204 days).
Specimen TARGET-10-PAPFAT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a992e039-1201-4385-a467-7d37dcbc4f36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFAT-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFAT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d306f692-d865-4dc1-8985-27c937f63f6a

The open-access MAF lists 17 somatic variants for this specimen: 5 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 3, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs782785913, COSV52349047; called by muse, mutect2, varscan2
- PAX2 | c.809G>A p.R270H (on ENST00000428433 / NM_003987.5; = p.R247H on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747639879, COSV62290441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.109_113delinsTGAGCAGGACT p.E37_P38delins* | Nonsense Mutation (INS) | VAF 34/91 reads (37%) | called by pindel, varscan2*
- JAKMIP3 | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TRAJ38 | c.2_3insTGGGA p.N2Mfs*10 | Frame Shift Ins (INS) | VAF 54/71 reads (76%) | called by mutect2, pindel*, varscan2*
- ABCA4 | c.4419G>T p.L1473= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- DNAH2 | c.9177G>A p.Q3059= | Silent (SNP) | VAF 12/15 reads (80%) | called by muse, varscan2
- KCNA4 | c.153C>A p.V51= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs60942363, COSV100068425, COSV60251501; called by muse, mutect2, varscan2
- KCNC2 | c.1317T>G p.G439= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV54361394, COSV54365534; called by muse, mutect2, varscan2
- PCNX2 | c.2832G>A p.V944= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- SOX9 | c.33C>T p.T11= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- YME1L1 | c.159C>T p.P53= | Silent (SNP) | VAF 68/176 reads (39%) | catalogued as COSV58761784; called by muse, mutect2, varscan2
- ZC3H12C | c.376T>C p.L126= | Silent (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- GSTM2 | c.*935G>A | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- LAMA1 | c.8095-60G>A | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs775914341; called by muse, mutect2, varscan2
- SAT1 | c.-90C>T | 5'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- SNX29P1 | n.70C>T | RNA (SNP) | VAF 13/39 reads (33%) | catalogued as rs551062077; called by muse, mutect2, varscan2
